Somatic mutation profile of tumor specimen 0DMIOT from CCDI case PBCALX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.0 years (2,553 days).
Specimen 0DMIOT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecf3e7f5-bd14-418d-80b0-6bf80c53eceb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMIPJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7cbc753-808e-41e1-8530-4c5b67c2330e

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED23 | c.3807+2T>C p.X1269_splice | Splice Site (SNP) | VAF 103/163 reads (63%) | catalogued as COSV100645232; called by muse, mutect2, varscan2
- NLRC4 | c.1385A>G p.H462R | Missense Mutation (SNP) | VAF 40/548 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- RGN | c.*67C>T | 3'UTR (SNP) | VAF 25/202 reads (12%) | called by muse, mutect2, varscan2
- TP73 | c.-10C>T | 5'UTR (SNP) | VAF 120/422 reads (28%) | catalogued as rs777305219; called by muse, mutect2
